Somatic mutation profile of tumor specimen TCGA-2Z-A9JM-01A (aliquot TCGA-2Z-A9JM-01A-12D-A42J-10) from TCGA case TCGA-2Z-A9JM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 28.3 years (10,323 days).
Specimen TCGA-2Z-A9JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12d4d8c9-4388-4f12-abe6-76c40ed3c78b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JM-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JM-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2022a989-4b33-48f9-a170-7ebb40ac931e

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Frame Shift Del 4, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99856961; called by muse, mutect2, varscan2
- AMIGO2 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as rs759997612, COSV99873630; called by muse, mutect2, varscan2
- ASAH2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753831322, COSV100269971; called by muse, mutect2, varscan2
- BRWD1 | c.323G>T p.R108M | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100313554; called by muse, mutect2, varscan2
- CACNA1G | c.6755A>G p.Q2252R | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV100661948; called by muse, mutect2, varscan2
- CACNA1H | c.5882C>T p.P1961L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52353206; called by muse, mutect2, varscan2
- CCL27 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV99426509; called by muse, mutect2, varscan2
- CFAP61 | c.2503+2T>A p.X835_splice | Splice Site (SNP) | VAF 22/122 reads (18%) | catalogued as rs750992545, COSV99845279; called by muse, mutect2, varscan2
- CHMP1B | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs772587665, COSV99303675; called by muse, mutect2, varscan2
- CWC22 | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844348; called by muse, mutect2, varscan2
- DNAH5 | c.2399A>T p.E800V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99450703; called by muse, mutect2, varscan2
- FBXO16 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV100672342; called by muse, mutect2, varscan2
- FKBP4 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs1262487103, COSV99133787; called by muse, mutect2, varscan2
- GALNT16 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61886075; called by muse, mutect2, varscan2
- HDAC8 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV101002373; called by muse, mutect2, varscan2
- ICE1 | c.6142A>G p.K2048E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1169073105, COSV99664942; called by muse, mutect2, varscan2
- IL17RC | c.1899G>C p.W633C (on ENST00000295981 / NM_153461.4; = p.W547C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99925828; called by muse, mutect2, varscan2
- KNCN | c.256C>A p.H86N (on ENST00000481882 / NM_001322255.2; = p.H63N on NM_001097611.1) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.08); catalogued as COSV99606305; called by muse, mutect2, varscan2
- KNCN | c.255C>G p.D85E (on ENST00000481882 / NM_001322255.2; = p.D62E on NM_001097611.1) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV99606306; called by muse, mutect2, varscan2
- LPAR6 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99925150; called by muse, mutect2, varscan2
- LRRN3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 63/340 reads (19%) | catalogued as COSV100071225; called by muse, mutect2, varscan2
- OXA1L | c.896A>T p.N299I (on ENST00000285848; = p.N239I on NM_005015.5) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99591177; called by muse, mutect2, varscan2
- PAK4 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100426530; called by muse, mutect2, varscan2
- PARP6 | c.1883A>C p.Y628S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.969); catalogued as COSV99536105; called by muse, varscan2
- PHF12 | c.2499T>A p.C833* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99255854; called by muse, mutect2, varscan2
- PPP1R12A | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99700450; called by muse, mutect2, varscan2
- PPRC1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV99531742; called by muse, mutect2, varscan2
- RABAC1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99706056; called by muse, mutect2, varscan2
- RASSF6 | c.254A>T p.K85I (on ENST00000342081 / NM_201431.2; = p.K53I on NM_177532.5) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100274989; called by muse, mutect2, varscan2
- RPS6KA5 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV100002322, COSV100002702; called by muse, mutect2, varscan2
- SLC35A1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV101060074, COSV65779789; called by muse, mutect2, varscan2
- SPATS1 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1049089138, COSV55822315, COSV55823293, COSV99913433; called by muse, mutect2, varscan2
- SPDYC | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV101017229; called by muse, mutect2, varscan2
- SPTBN2 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs1035435319, COSV100017939, COSV100019618, COSV59454169; called by muse, mutect2, varscan2
- TCHH | c.3046T>C p.W1016R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1473961394, COSV64273199; called by muse, mutect2
- THADA | c.4925C>G p.A1642G | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as COSV100368821; called by muse, mutect2, varscan2
- TIGIT | c.524T>G p.V175G | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101048105; called by muse, mutect2, varscan2
- TIMMDC1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99956195; called by muse, mutect2, varscan2
- ZMYM3 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as rs1180331578, COSV100077993; called by muse, mutect2, varscan2
- ZNF335 | c.2065C>A p.H689N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100533110; called by muse, mutect2, varscan2
- ZNRF3 | c.1441G>A p.E481K (on ENST00000544604 / NM_001206998.2; = p.E381K on NM_032173.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV100238542; called by muse, mutect2, varscan2
- BEST1 | c.564dup p.A189Cfs*43 | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- CD109 | c.2775_2776dup p.M926Tfs*2 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- CECR2 | c.2870del p.P957Lfs*83 (on ENST00000342247 / NM_001290047.2; = p.P774Lfs*82 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 63/226 reads (28%) | called by mutect2, pindel, varscan2
- LPO | c.1189del p.L397* | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- RUNDC1 | c.373del p.E125Sfs*14 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- ZNF225 | c.514del p.R172Efs*86 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- ZNF84 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCD4 | c.555C>T p.L185= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs188108983; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADSS2 | c.117C>T p.G39= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV100836856; called by muse, mutect2, varscan2
- ARFRP1 | c.501C>G p.A167= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs953852819, COSV99423054; called by muse, mutect2, varscan2
- BCAR1 | c.2520T>A p.P840= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99366789; called by muse, mutect2, varscan2
- DHX57 | c.3027A>G p.L1009= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99769609; called by muse, mutect2, varscan2
- HECTD4 | c.7185G>A p.L2395= | Silent (SNP) | VAF 138/324 reads (43%) | catalogued as COSV101107743; called by muse, mutect2, varscan2
- IMPACT | c.348A>G p.K116= | Silent (SNP) | VAF 91/343 reads (27%) | catalogued as rs180787047, COSV99408850; called by muse, mutect2, varscan2
- LCE2B | c.186C>T p.G62= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV100909317; called by muse, mutect2, varscan2
- MTMR10 | c.675G>C p.S225= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100076154, COSV58728390; called by muse, mutect2, varscan2
- NEDD4 | c.2565G>A p.R855= (on ENST00000508342 / NM_001284338.1; = p.R436= on NM_006154.4) | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV100163788; called by muse, mutect2, varscan2
- NRCAM | c.2319C>T p.F773= (on ENST00000379028 / NM_001371124.1; = p.F757= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs761612559, COSV100694187; called by muse, mutect2, varscan2
- SLC44A3 | c.1182C>A p.I394= (on ENST00000271227 / NM_001114106.3; = p.I346= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV99598290; called by muse, mutect2, varscan2
- SMG7 | c.3207C>T p.S1069= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100750365; called by muse, mutect2, varscan2
- TNPO2 | c.1815C>A p.V605= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV100790369; called by muse, mutect2, varscan2
- VANGL1 | c.756G>T p.L252= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100049228; called by muse, mutect2
- ZNF613 | c.870C>T p.C290= (on ENST00000293471 / NM_001031721.4; = p.C254= on NM_024840.4) | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV99522951; called by muse, mutect2, varscan2
- GLS | c.1650+1220A>G | Intron (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100290187; called by muse, mutect2, varscan2
